Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A39L, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A39L-01A (Primary Tumor).

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1. THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

1C5-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9
hw
9/14/11

TUMOR SITE:

Left lobe

HISTOLOGIC TYPE:

Papillary carcinoma, with conventional and follicular features

TUMOR SIZE (LARGEST NODULE):

5.5 cm

FOCALITY:

Unifocal

LYMPH NODES (INCLUDES ALL PARTS):

All four (4) perithyroidal lymph nodes are negative for tumor.

EXTENT OF INVASION (STAGING):

pT3: Tumor > 4 cm, limited to thyroid

REGIONAL LYMPH NODES:

pN0: No regional lymph node metastasis (incidental perithyroidal lymph nodes examined only)

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Margins are uninvolved

VENOUS/LYMPHATIC INVASION:

None identified

ADDITIONAL PATHOLOGIC FINDINGS:

Parathyroid tissue

Adenomatoid nodule

NOTE: This case was shown at the

Source: NCI Genomic Data Commons file df35914f-39e3-4523-9b90-6fb61d8c05e0 (TCGA-ET-A39L.C284BB2D-209D-42BD-9DDC-DD5C152BE2CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).